Somatic mutation profile of tumor specimen C3N-03757-07 (aliquot CPT0248040006) from CPTAC case C3N-03757, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.7 years (26,559 days).
Specimen C3N-03757-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fbe617f-8dd4-497b-bc2b-11caf7620e1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03757-31 (Blood Derived Normal), aliquot CPT0248070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87b771e5-ea29-4c50-9efc-ea7d584d61d0

The open-access MAF lists 135 somatic variants for this specimen: 89 protein-altering or splice-affecting, 31 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 31, Intron 5, Frame Shift Del 5, RNA 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Region 3, 5'Flank 2, 5'UTR 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 67/105 reads (64%) | catalogued as rs128626235, CD951679, CM940337, COSV99920124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4998dup p.P1667Sfs*15 (on ENST00000358273 / NM_001042492.3; = p.P1646Sfs*15 on NM_000267.3) | Frame Shift Ins (INS) | VAF 98/312 reads (31%) | catalogued as rs1135402867; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.5608C>T p.R1870W (on ENST00000358273 / NM_001042492.3; = p.R1849W on NM_000267.3) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049849034, COSV62192493; called by muse, mutect2
- PTPN11 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 144/546 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs747833359; called by muse, mutect2, varscan2
- ADAMTS17 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 169/503 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748878355, COSV51495029; called by muse, mutect2, varscan2
- ALPK1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774069152; called by muse, mutect2, varscan2
- ANO4 | c.1132A>T p.T378S (on ENST00000392977 / NM_001286615.2; = p.T343S on NM_178826.4) | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.801); catalogued as rs1248290977; called by muse, mutect2, varscan2
- C1QTNF8 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs750666150; called by muse, mutect2, varscan2
- CNTN6 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs574681005, COSV63161392, COSV63171458; called by muse, mutect2, varscan2
- DENND1C | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs746690717; called by muse, mutect2, varscan2
- DNAH12 | c.6062G>A p.R2021H (on ENST00000351747; = p.R2040H on NM_001366028.2) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs949887032, COSV61060232; called by muse, mutect2, varscan2
- DNAI2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 164/574 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767482061; called by muse, mutect2, varscan2
- GABRR2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754042657, COSV68765110, COSV68766312; called by muse, mutect2, varscan2
- HEATR1 | c.3035C>G p.S1012C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV63981723; called by muse, mutect2, varscan2
- HNRNPA1 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52937907; called by muse, mutect2, varscan2
- HPX | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs559750586, COSV56419568; called by muse, mutect2, varscan2
- IGHV3-35 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.736); catalogued as rs765476090; called by muse, mutect2, varscan2
- KLHL36 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.894); catalogued as rs1331263177, COSV50721078; called by muse, mutect2, varscan2
- KLK9 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as rs576163713; called by muse, mutect2, varscan2
- KPRP | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV64221696; called by muse, mutect2, varscan2
- KRTAP10-8 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs753364581; called by muse, mutect2, varscan2
- LRRC1 | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753614350; called by muse, mutect2, varscan2
- MUC12 | c.1727G>A p.R576H (on ENST00000379442; = p.R433H on NM_001164462.1) | Missense Mutation (SNP) | VAF 93/959 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.517); catalogued as rs758251011; called by muse, mutect2, varscan2
- MYH8 | c.5734C>T p.R1912W | Missense Mutation (SNP) | VAF 134/432 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751931786; called by muse, mutect2, varscan2
- NCSTN | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 178/441 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201152756, COSV54187792; called by muse, mutect2, varscan2
- NLRP3 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 191/606 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs772009059, COSV100276465, COSV60228880; called by muse, mutect2, varscan2
- NLRP5 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as rs374971021, COSV66763712; called by muse, mutect2, varscan2
- NRXN2 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.727); catalogued as rs774679959; called by muse, mutect2, varscan2
- OR2L3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs755534000, COSV63456299; called by muse, mutect2, varscan2
- OR8J1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs752525289, COSV57316740; called by muse, mutect2, varscan2
- OSTF1 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs1228636236; called by muse, mutect2, varscan2
- PDZD7 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1160650482, COSV56520228, COSV56520961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R1 | c.579dup p.P194Tfs*12 | Frame Shift Ins (INS) | VAF 35/293 reads (12%) | catalogued as COSV57134246; called by mutect2, pindel, varscan2
- PLEC | c.5831G>A p.R1944H (on ENST00000322810 / NM_201380.4; = p.R1834H on NM_000445.5) | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782737003; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHG3 | c.830G>A p.R277Q (on ENST00000394691; = p.R333Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs564138747, COSV99906472; called by muse, mutect2, varscan2
- PRRC2A | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1436436810, COSV101051269; called by muse, mutect2, varscan2
- RAB11FIP4 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100364986; called by muse, mutect2, varscan2
- RFX6 | c.2464G>A p.V822I | Missense Mutation (SNP) | VAF 138/369 reads (37%) | SIFT tolerated, low confidence (0.57); PolyPhen probably damaging (0.985); catalogued as rs373007099; ClinVar: uncertain significance; called by muse, varscan2
- SATL1 | c.499C>T p.R167* (on ENST00000395409; = p.R354* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 72/108 reads (67%) | catalogued as rs374764586, COSV60575818; called by muse, mutect2, varscan2
- SCIN | c.1317G>T p.T439= (on ENST00000297029 / NM_001112706.3; = p.T192= on NM_033128.3) | Splice Region (SNP) | VAF 34/118 reads (29%) | catalogued as rs771879066, COSV51692773; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 62/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SIGLEC5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 107/572 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs1360404047; called by muse, mutect2, varscan2
- SOX5 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100507627; called by muse, mutect2, varscan2
- TACC2 | c.5041C>T p.P1681S | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs775285828, COSV100551667; called by muse, mutect2, varscan2
- TAS2R43 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT tolerated (0.98); PolyPhen benign (0.023); catalogued as COSV67858624; called by muse, mutect2, varscan2
- TMEM250 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 129/465 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs1246746879; called by muse, mutect2, varscan2
- UGT2B11 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1481379480; called by muse, mutect2
- UGT2B7 | c.457A>C p.I153L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs761849480; called by muse, mutect2, varscan2
- WBP1L | c.24_27del p.Q9Ifs*46 | Frame Shift Del (DEL) | VAF 30/260 reads (12%) | catalogued as rs1348526072; called by mutect2, pindel, varscan2
- ACE | c.3704G>T p.G1235V | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACKR4 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAR | c.1763C>G p.S588C | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ATP12A | c.2590C>T p.L864F | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCOR | c.1680_1681del p.S562Efs*48 | Frame Shift Del (DEL) | VAF 68/133 reads (51%) | called by mutect2, pindel, varscan2
- BTBD8 | c.1451C>G p.T484R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); called by muse, varscan2
- C3orf62 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, varscan2
- CHD4 | c.2228G>C p.G743A (on ENST00000357008 / NM_001363606.2; = p.G756A on NM_001273.5) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- COL17A1 | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DUOX1 | c.2136G>A p.L712= | Splice Region (SNP) | VAF 57/360 reads (16%) | called by muse, mutect2, varscan2
- ENPP3 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EXOSC9 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EYS | c.7200T>A p.Y2400* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2
- FAAH | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GDPD4 | c.473T>G p.L158* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- GGN | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HARBI1 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFT140 | c.4386_4387del p.*1463Rfs*56 | Frame Shift Del (DEL) | VAF 57/201 reads (28%) | called by mutect2, pindel, varscan2
- KCNH2 | c.2286dup p.A763Cfs*41 | Frame Shift Ins (INS) | VAF 72/335 reads (21%) | called by mutect2, pindel, varscan2
- MARCHF5 | c.701_705del p.N234Tfs*18 | Frame Shift Del (DEL) | VAF 47/86 reads (55%) | called by mutect2, pindel
- MCTP2 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MRTFB | c.64A>G p.S22G | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYO15A | c.4786A>C p.S1596R | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- NIN | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- OR2L3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR2T3 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR51F2 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PCLAF | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIEZO2 | c.2856G>C p.W952C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, varscan2
- PLEKHG2 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PPME1 | c.1077A>G p.V359= | Splice Region (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2
- PPP3CC | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SEC31A | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SPEF2 | c.926A>T p.K309I | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF4B | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TOPORS | c.1315T>G p.L439V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRHDE | c.445C>A p.H149N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- UGT2B7 | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZBTB10 | c.2323del p.D775Ifs*15 (on ENST00000430430; = p.D751Ifs*15 on NM_023929.4) | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | called by mutect2, pindel
- ADAM15 | c.1947G>A p.V649= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs1260923090, COSV55124958; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.168G>A p.G56= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs1473679738; called by muse, mutect2, varscan2
- BIRC3 | c.1617T>C p.V539= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- CACNA1B | c.492C>T p.N164= | Silent (SNP) | VAF 37/263 reads (14%) | catalogued as rs756422106, COSV53127102; called by muse, mutect2, varscan2
- DNM1 | c.2199C>T p.H733= | Silent (SNP) | VAF 104/629 reads (17%) | catalogued as COSV57855538; called by muse, mutect2, varscan2
- DOCK2 | c.1323C>T p.T441= | Silent (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- DPP7 | c.495G>A p.G165= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- DSG4 | c.789C>T p.N263= | Silent (SNP) | VAF 106/196 reads (54%) | catalogued as rs148802079; called by muse, mutect2, varscan2
- FOXB2 | c.225G>A p.P75= | Silent (SNP) | VAF 137/444 reads (31%) | called by muse, mutect2, varscan2
- GGTLC2 | c.261C>T p.N87= | Silent (SNP) | VAF 41/254 reads (16%) | catalogued as rs562251910; called by muse, mutect2, varscan2
- KCNJ14 | c.213G>A p.A71= | Silent (SNP) | VAF 52/210 reads (25%) | called by muse, mutect2, varscan2
- KCNQ1 | c.867C>T p.N289= | Silent (SNP) | VAF 75/256 reads (29%) | catalogued as rs1262523905, COSV99328068; called by muse, mutect2, varscan2
- LORICRIN | c.708C>T p.G236= | Silent (SNP) | VAF 83/238 reads (35%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1209G>A p.A403= | Silent (SNP) | VAF 78/179 reads (44%) | catalogued as rs548430409, COSV59669914; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRIT2 | c.867C>A p.P289= | Silent (SNP) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- LRP1 | c.12003C>T p.D4001= | Silent (SNP) | VAF 74/222 reads (33%) | catalogued as rs1271485088, COSV54526580; called by muse, mutect2, varscan2
- MAG | c.576C>T p.D192= | Silent (SNP) | VAF 127/434 reads (29%) | catalogued as COSV62700329; called by muse, mutect2, varscan2
- MAP7 | c.825T>C p.F275= | Silent (SNP) | VAF 82/246 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.24513G>A p.Q8171= | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as rs747208126, COSV101200259; called by muse, mutect2, varscan2
- MYBPC3 | c.2229G>A p.K743= | Silent (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- NPAS4 | c.360C>T p.Y120= | Silent (SNP) | VAF 93/317 reads (29%) | catalogued as rs377576767, COSV60650442; called by muse, mutect2, varscan2
- PCDHGA5 | c.1710C>T p.D570= | Silent (SNP) | VAF 145/456 reads (32%) | catalogued as COSV54004662, COSV54016738; called by muse, mutect2, varscan2
- PLEKHH3 | c.2130C>T p.A710= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs1345004929; called by muse, mutect2, varscan2
- PXDN | c.2307C>T p.S769= | Silent (SNP) | VAF 95/545 reads (17%) | catalogued as rs769712122, COSV53228345; called by muse, mutect2, varscan2
- RFX6 | c.2562G>A p.S854= | Silent (SNP) | VAF 114/355 reads (32%) | catalogued as rs535297853; called by muse, varscan2
- RUBCN | c.252C>T p.F84= | Silent (SNP) | VAF 126/527 reads (24%) | catalogued as rs768108966, COSV99584229; called by muse, mutect2
- SHMT1 | c.990G>A p.Q330= | Silent (SNP) | VAF 93/320 reads (29%) | called by muse, mutect2, varscan2
- SPRY3 | c.819C>T p.I273= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as COSV57144636; called by muse, mutect2, varscan2
- TGM6 | c.843G>T p.L281= | Silent (SNP) | VAF 81/343 reads (24%) | called by muse, mutect2, varscan2
- TPO | c.1110C>T p.R370= | Silent (SNP) | VAF 112/321 reads (35%) | catalogued as rs1190155346, COSV61097064; called by muse, mutect2, varscan2
- ZIC3 | c.231G>A p.Q77= | Silent (SNP) | VAF 70/102 reads (69%) | called by muse, varscan2
- AC073648.1 | n.428G>A | RNA (SNP) | VAF 71/191 reads (37%) | catalogued as rs950173828; called by muse, mutect2, varscan2
- ADAD2 | c.-4G>A | 5'UTR (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- ATP11AUN | n.1104C>T | RNA (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- BEST1 | chr11:61964953 del TCC | 3'Flank (DEL) | VAF 124/482 reads (26%) | called by pindel, varscan2
- BHLHE22 | chr8:64576383 G>A | 5'Flank (SNP) | VAF 103/317 reads (32%) | called by muse, mutect2, varscan2
- CASP8 | c.803-2940C>T | Intron (SNP) | VAF 47/486 reads (10%) | called by muse, mutect2
- DIO3 | chr14:101557662 G>A | 5'Flank (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- LTBP4 | c.2759-64G>C | Intron (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2, varscan2
- MYO5A | c.-11C>T | 5'UTR (SNP) | VAF 77/243 reads (32%) | catalogued as rs1193949352; called by muse, mutect2, varscan2
- SLC41A3 | c.1366+64del | Intron (DEL) | VAF 88/333 reads (26%) | called by mutect2, pindel, varscan2
- SNURFL | n.279G>A | RNA (SNP) | VAF 50/69 reads (72%) | catalogued as rs759760357; called by muse, mutect2, varscan2
- SURF1 | c.*36C>T | 3'UTR (SNP) | VAF 42/300 reads (14%) | called by muse, mutect2, varscan2
- TAF2 | c.3109-612G>A | Intron (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- TOM1L2 | c.1279-10G>A | Intron (SNP) | VAF 40/234 reads (17%) | catalogued as rs757323615; called by muse, mutect2, varscan2
- UGT2B27P | n.1490G>T | RNA (SNP) | VAF 156/450 reads (35%) | catalogued as rs753223808; called by muse, mutect2
